Somatic mutation profile of tumor specimen MMRF_2015_1_BM_CD138pos (aliquot MMRF_2015_1_BM_CD138pos_T1_KHS5U_L08090) from MMRF case MMRF_2015, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.0 years (23,749 days).
Specimen MMRF_2015_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35ff169e-3f06-4a79-8868-edccfa17e6e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2015_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2015_1_PB_CD3pos_C2_KHS5U_L08091; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7c6b945-d33c-4e49-bb27-9999d3c3cc4c

The open-access MAF lists 76 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 16, Intron 9, Silent 7, 5'Flank 6, RNA 4, 5'UTR 4, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 63/63 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALX1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57491921; called by muse, varscan2
- AQP4 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV101270559, COSV67218294; called by muse, mutect2
- AUTS2 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61425189; called by muse, mutect2, varscan2
- CATSPER2 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28660230, COSV100390504; called by muse, varscan2
- DDA1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs766625782, COSV100724772; called by muse, varscan2
- EPHA5 | c.1985C>A p.A662D | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56668549; called by muse, mutect2, varscan2
- IGHV1-69 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.047); catalogued as rs11557983; called by muse, mutect2, varscan2
- IGHV4-34 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as rs1354511622; called by muse, mutect2, varscan2
- KLHDC7A | c.1921G>A p.G641S | Missense Mutation (SNP) | VAF 76/136 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757275158; called by muse, mutect2, varscan2
- KLHL40 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs762744469; called by muse, mutect2, varscan2
- MAP2 | c.3989A>G p.E1330G | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs976365071; called by muse, mutect2, varscan2
- RANBP6 | c.1513C>G p.L505V | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs767418443; called by muse, mutect2, varscan2
- RTN4RL2 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 161/309 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV58652075; called by muse, mutect2, varscan2
- ZBTB38 | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 161/318 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs747459711, COSV58540119; called by muse, mutect2, varscan2
- AHDC1 | c.1913G>A p.W638* | Nonsense Mutation (SNP) | VAF 99/178 reads (56%) | called by muse, mutect2, varscan2
- AMBRA1 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- BASP1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BSPRY | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRLF2 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 66/66 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); called by muse, varscan2
- DHX15 | c.1787-5T>G | Splice Region (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- GJD4 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2
- IGKJ4 | c.2T>G p.L1R | Missense Mutation (SNP) | VAF 37/76 reads (49%) | PolyPhen benign (0.062); called by muse, varscan2
- MARS1 | c.539A>C p.E180A | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MLIP | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- POF1B | c.1670T>C p.I557T | Missense Mutation (SNP) | VAF 67/67 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PRKD2 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 108/118 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SNRPB | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC13C | c.615A>T p.K205N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- VMA21 | c.29A>T p.N10I | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, varscan2
- AK5 | c.1317C>T p.I439= (on ENST00000354567 / NM_174858.3; = p.I413= on NM_012093.4) | Silent (SNP) | VAF 63/138 reads (46%) | catalogued as rs538601394, COSV60974482; called by muse, mutect2, varscan2
- DCAF5 | c.48C>T p.G16= | Silent (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.123C>T p.C41= | Silent (SNP) | VAF 56/60 reads (93%) | catalogued as rs377265996; called by muse, varscan2
- IGHV2-70 | c.120C>T p.T40= | Silent (SNP) | VAF 52/56 reads (93%) | catalogued as rs538449396; called by muse, varscan2
- MYCN | c.285C>T p.D95= | Silent (SNP) | VAF 52/133 reads (39%) | called by muse, mutect2, varscan2
- NPAS3 | c.507A>G p.G169= (on ENST00000356141 / NM_001164749.2; = p.G137= on NM_022123.3) | Silent (SNP) | VAF 79/154 reads (51%) | called by muse, mutect2, varscan2
- SORL1 | c.192G>A p.G64= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, varscan2
- AL592293.1 | n.984A>G | RNA (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- ASPRV1 | chr2:69964468 C>G | 5'Flank (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- BACH2 | c.*2465G>T | 3'UTR (SNP) | VAF 28/28 reads (100%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020689 T>G | 5'Flank (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2
- C16orf54 | c.*957A>G | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- CBARP | c.293-96C>T | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- CCDC171 | c.*1336A>G | 3'UTR (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- CCDC6 | c.*2670C>G | 3'UTR (SNP) | VAF 126/147 reads (86%) | called by muse, mutect2, varscan2
- CNTN3 | c.*228A>G | 3'UTR (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- COL5A2 | c.*678_*685del | 3'UTR (DEL) | VAF 38/77 reads (49%) | called by mutect2, pindel, varscan2
- DDHD2 | c.1126-614A>G | Intron (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1512+821G>A | Intron (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- FSTL5 | c.*629G>C | 3'UTR (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- GEM | c.331+36A>G | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- GYPA | c.*472T>C | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.171A>T | RNA (SNP) | VAF 46/143 reads (32%) | catalogued as rs746861388; called by muse, varscan2
- IGKV2-29 | n.57G>A | RNA (SNP) | VAF 52/127 reads (41%) | catalogued as rs777860767; called by muse, mutect2
- IGLL5 | c.-146G>A | 5'UTR (SNP) | VAF 38/85 reads (45%) | catalogued as rs1432501105; called by muse, mutect2, varscan2
- IMMP2L | c.305+553A>T | Intron (SNP) | VAF 87/155 reads (56%) | called by muse, mutect2, varscan2
- LIMD2 | c.43-14C>T | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851316 T>A | 5'Flank (SNP) | VAF 98/194 reads (51%) | called by muse, varscan2
- MIR5195 | chr14:106851370 T>C | 5'Flank (SNP) | VAF 82/172 reads (48%) | catalogued as rs1263321431; called by muse, varscan2
- MOB1B | c.409+41C>G | Intron (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- MUCL1 | c.-14G>T | 5'UTR (SNP) | VAF 89/202 reads (44%) | called by muse, mutect2, varscan2
- PARVA | c.*586T>G | 3'UTR (SNP) | VAF 62/124 reads (50%) | called by muse, mutect2, varscan2
- PDPK2P | n.357C>T | RNA (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- PTGER3 | c.*588G>A | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, varscan2
- RNA5S17 | chr1:228650707 G>T | 5'Flank (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- RXFP3 | c.-332A>G | 5'UTR (SNP) | VAF 28/72 reads (39%) | catalogued as rs1342561727; called by muse, mutect2, varscan2
- SEMA7A | c.1639+110C>T | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- TLCD4 | c.*845A>G | 3'UTR (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975590 C>G | 5'Flank (SNP) | VAF 112/112 reads (100%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- TRIM68 | c.*202A>G | 3'UTR (SNP) | VAF 82/154 reads (53%) | catalogued as rs561443068; called by muse, mutect2, varscan2
- UNC5D | c.*5392A>T | 3'UTR (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- VAV3 | c.*854C>G | 3'UTR (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2
- VMA21 | c.-13G>C | 5'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, varscan2
- ZADH2 | c.*4155C>A | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.784+825G>A | Intron (SNP) | VAF 50/95 reads (53%) | called by mutect2, varscan2
- ZNF331 | c.*370C>T | 3'UTR (SNP) | VAF 42/46 reads (91%) | catalogued as rs897352406; called by muse, mutect2, varscan2
